Somatic mutation profile of tumor specimen TCGA-BB-4225-01A (aliquot TCGA-BB-4225-01A-01D-1434-08) from TCGA case TCGA-BB-4225, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G3; Age at diagnosis: 73.1 years (26,687 days).
Specimen TCGA-BB-4225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f022274-b6c7-4f74-be5f-3508122977c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4225-10A (Blood Derived Normal), aliquot TCGA-BB-4225-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b323f2-710f-49ec-b35e-68d01b818a74

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 42, Silent 23, Nonsense Mutation 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as rs1276707545, COSV99288668; called by muse, mutect2, varscan2
- ABCA7 | c.5233C>T p.L1745F | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CD166825, COSV99566241; called by muse, mutect2, varscan2
- ACOXL | c.789-1G>A p.X263_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV101095679; called by muse, mutect2, varscan2
- ACR | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs748831621, COSV99334535; called by muse, mutect2
- ANKRD34A | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041288, COSV100041371, COSV60162212; called by muse, mutect2, varscan2
- ASAP3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100369610; called by muse, mutect2, varscan2
- ASAP3 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as rs775567666, COSV100369611; called by muse, varscan2
- ATG16L1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs774776145, COSV100731361, COSV100731375, COSV100731385; called by muse, mutect2, varscan2
- BCKDK | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV99570807; called by muse, mutect2, varscan2
- BMP2K | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as rs1398852922, COSV100621910, COSV58601090; called by muse, mutect2
- BTNL2 | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100896183; called by muse, mutect2, varscan2
- CCDC17 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs779922193, COSV100601962; called by muse, mutect2, varscan2
- CILP2 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 150/734 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs566423223, COSV52273907; called by muse, mutect2, varscan2
- CRNN | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55123937; called by muse, mutect2, varscan2
- CROT | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV99711082; called by muse, mutect2, varscan2
- CYP11B1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs144224988; called by muse, mutect2, varscan2
- DHX34 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs1194632658, COSV100169852; called by muse, mutect2, varscan2
- EFCAB13 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.654); catalogued as rs1433569041, COSV100516835; called by muse, mutect2, varscan2
- EPHX2 | c.1291A>G p.N431D | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs775534758, COSV100994751; called by muse, mutect2, varscan2
- FBXO43 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs549146365, COSV71053719; called by muse, mutect2, varscan2
- FCRLB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 95/385 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs939842337, COSV100396340; called by muse, mutect2, varscan2
- FDXR | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272743821, COSV99502360; called by muse, mutect2, varscan2
- FRMPD3 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as rs866908462, COSV99346886; called by muse, mutect2
- GHSR | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs776346975, COSV99577153; called by muse, mutect2, varscan2
- GPATCH2 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.388); catalogued as COSV100861824; called by muse, mutect2, varscan2
- GSDMA | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV99228005; called by muse, mutect2, varscan2
- HECTD3 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV55799729; called by muse, mutect2, varscan2
- KCNJ16 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs375371610; called by muse, mutect2, varscan2
- KIF21B | c.3880C>T p.R1294W (on ENST00000422435 / NM_001252100.2; = p.R1281W on NM_017596.4) | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1218953359, COSV59754651; called by muse, mutect2, varscan2
- MAGEB10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100775371; called by muse, mutect2
- MAPK4 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs763078166, COSV68541257; called by muse, mutect2, varscan2
- MROH2B | c.3518C>T p.T1173I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1433023228, COSV101270876; called by muse, mutect2, varscan2
- MUC16 | c.21466A>G p.S7156G | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV101201050; called by muse, mutect2, varscan2
- MYH3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.149); catalogued as COSV99878695; called by muse, mutect2, varscan2
- NLGN4Y | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100197045; called by muse, mutect2, varscan2
- NOTCH1 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53063613; called by muse, mutect2, varscan2
- PAG1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99597798; called by muse, mutect2, varscan2
- PCDHB13 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53394020; called by muse, mutect2, varscan2
- PGS1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as COSV99428468; called by muse, mutect2, varscan2
- PRR16 | c.230C>T p.T77M (on ENST00000407149 / NM_001300783.2; = p.T54M on NM_016644.2) | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759341558, COSV65404979; called by muse, mutect2, varscan2
- RYR2 | c.11032G>A p.E3678K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100772243, COSV63660651; called by muse, mutect2, varscan2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SLC6A15 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1316290501, COSV99881391; called by mutect2, varscan2
- SNRPB | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100293464; called by muse, varscan2
- THBS2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317152018, COSV100827847; called by muse, mutect2, varscan2
- TTN | c.24193C>T p.R8065C (on ENST00000591111; = p.R7138C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | PolyPhen benign (0.011); catalogued as rs776519143, COSV60234488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.3489C>T p.F1163= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs1456297535, COSV56855617; called by muse, mutect2, varscan2
- AKAP10 | c.1515G>A p.L505= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV99855559; called by muse, mutect2, varscan2
- ASRGL1 | c.870C>T p.D290= | Silent (SNP) | VAF 94/192 reads (49%) | catalogued as rs202153953; called by muse, mutect2, varscan2
- CLUH | c.930C>T p.F310= (on ENST00000435359; = p.F348= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs746019720, COSV70928683; called by muse, mutect2, varscan2
- CTTN | c.300C>T p.V100= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs574999868, COSV100098241; called by muse, mutect2, varscan2
- DLAT | c.1350C>T p.I450= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs587724011, COSV99734945; called by muse, mutect2, varscan2
- DOCK5 | c.864C>T p.D288= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99377589; called by muse, mutect2, varscan2
- FBXL18 | c.2067C>T p.D689= | Silent (SNP) | VAF 70/243 reads (29%) | catalogued as rs561424661, COSV101212080; called by muse, mutect2, varscan2
- FUCA2 | c.690C>T p.D230= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs377166178; called by muse, mutect2, varscan2
- GLT6D1 | c.282G>A p.P94= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs765609739, COSV65627602; called by muse, mutect2, varscan2
- GPR179 | c.1341C>T p.I447= (on ENST00000621958; = p.I446= on NM_001004334.4) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs960166683; called by muse, mutect2, varscan2
- LRP6 | c.2259C>T p.L753= | Silent (SNP) | VAF 15/235 reads (6%) | catalogued as rs750823651, COSV53786378; called by muse, mutect2
- MFGE8 | c.261C>T p.A87= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs777632087, COSV99183976; called by muse, mutect2, varscan2
- PCDHA11 | c.132C>T p.F44= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as rs782755765, COSV56542885; called by muse, mutect2, varscan2
- PCDHGB1 | c.2121C>T p.I707= | Silent (SNP) | VAF 70/313 reads (22%) | catalogued as COSV99528907; called by muse, mutect2, varscan2
- PCNX2 | c.3744G>A p.L1248= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99269133; called by muse, mutect2, varscan2
- PLCB3 | c.3063G>A p.T1021= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs780909572, COSV99657672; called by muse, mutect2, varscan2
- RBM15 | c.102C>T p.L34= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1182968641, COSV100873491; called by muse, mutect2, varscan2
- RPN2 | c.423C>T p.S141= | Silent (SNP) | VAF 11/286 reads (4%) | catalogued as COSV99411984; called by muse, mutect2
- SALL3 | c.1944G>A p.P648= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs373055868, COSV73305969; called by muse, mutect2
- SHFL | c.681G>A p.K227= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as rs748736911, COSV53462068; called by muse, mutect2, varscan2
- SVEP1 | c.9144C>T p.A3048= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as rs371371607; called by muse, mutect2, varscan2
- WDR53 | c.18G>A p.T6= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs556124469, COSV100218125, COSV60283924; called by muse, mutect2, varscan2
